Surgical pathology report (de-identified scan), TCGA case TCGA-CV-6935, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-6935-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

- (A) RIGHT VALLECULA, RIGHT PYRIFORM MARGIN:
SQUAMOUS CELL CARCINOMA IN SQUAMOUS MUCOSA.
- (B) LARYNX:
POORLY TO MODERATELY DIFFERENTIATED SQUAMOUS CELL CARCINOMA,
DEEPLY INVASIVE INVOLVING RIGHT SUPRAGLOTTIC REGION AND
EXTENDING TO RIGHT ARYEPIGLOTTIC FOLD.
EXTENSIVE PERINEURAL AND VASCULAR INVASION PRESENT.
METASTATIC SQUAMOUS CACINOMA IN FOUR LYMPH NODES WITH EXTRANODAL
EXTENSION.
- (C) ADDITIONAL MARGIN OF HEMOSTAT LATERAL:
FOCAL ATYPICAL CELLS SUSPICIOUS FOR SQUAMOUS CELL CARCINOMA.
- (D) BASE OF TONGUE, LATERAL OROPHARYNX RIGHT SIDE:
Squamous mucosa, negative for tumor.

Entire report and diagnosis completed by: [REDACTED]
Report released by: [REDACTED]

GROSS DESCRIPTION

(A) RIGHT VALLECULA, RIGHT PYRIFORM MARGIN - One tan-tissue fragment (2.6 x 0.2 x 0.3 cm). The lateral portion of the specimen is marked with black ink. Submitted entirely for frozen section diagnosis. [REDACTED]

*FS/DX: SQUAMOUS CELL CARCINOMA IN SQUAMOUS MUCOSA. [REDACTED]

(B) TOTAL WIDEFIELD LARYNGECTOMY - (9.0 x 7.0 x 4.5 cm), overall, consisting of a larynx, right lobe of thyroid (2.5 x 2.4 x 0.4 cm), hyoid bone and soft tissue.

There is an ulcerated, slightly firm supraglottic tumor (3.0 x 2.5 x 2.0 cm) which infringes on both the midline and the right pyriform sinus. The mucosa surrounding the tumor is irregularly thickened. The mucosal abnormalities extend the midline and laryngeal surface of the epiglottis.

Four lymph nodes (ranging from 0.5 x 1.2 cm are present in the pretracheal midline. No additional nodes are identified.

SECTION CODE: B1, grossly normal mucosa, right side near tumor; B2-B10, sequential sections of tumor from right to left; B11-B16, midline sections; B17, left transglottic section; B18, thyroid; B19, B20, pretracheal midline lymph nodes. [REDACTED]

(C) ADDITIONAL MARGIN OF A, HEMOSTAT LATERAL - A strip of tan-pink,

[page 2 of 2]
[REDACTED]

glistening mucosa and soft tissue (3.8 x 1.8 x 0.4 cm). A hemostat identifies the lateral margin.

SECTION CODE: C1, lateral aspect (ink at most lateral margin); C2, medial aspect of specimen (ink at medial most aspect) [REDACTED]

*FS/DX: ATYPICAL CELLS SUSPICIOUS FOR SQUAMOUS CELL CARCINOMA (SLIDE C1). [REDACTED]

(D) BASE OF TONGUE LATERAL OROPHARYNX RIGHT SIDE - A fragment of pink-tan mucosa (3.0 x 0.3 x 0.3 cm). Submitted entirely for frozen section. [REDACTED]

*FS/DX: SQUAMOUS MUCOSA, NO TUMOR PRESENT. [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 18d3c78a-f5fd-4593-b1c6-862c722261ba (TCGA-CV-6935.3BCDEF42-661B-4AA1-98AE-97DAA8BAE390.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).